Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A4ZQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A4ZQ-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Final Report

DIAGNOSIS

LIVER, RIGHT PARTIAL HEPATECTOMY SEGMENT 7:

1. Hepatocellular carcinoma:
- a. Nuclear grade: 2 of 3 (Lauwers grade)
- b. Size: 9.5 cm
- c. Angiolymphatic invasion: Absent
- d. Margin: Negative (0.4 cm)
2. Background liver shows inactive cirrhosis compatible with clinical history of hepatitis C (grade 1 of 4, stage 4 of 4)

2010 LIVER HEPATOCELLULAR CANCER STAGING PARAMETERS

Case number: [REDACTED] Patient name: [REDACTED]

Final TNM: pT1NXM0

2010 stage: I

MACROSCOPIC

SPECIMEN TYPE

Segmentectomy

Right partial hepatectomy of segment 7

TUMOR TYPE

Single without satellites

TUMOR SIZE

9.5 cm

ICD-0-3

carcinoma, hepatocellular, NOS 8170/3

Site: Liver C22.0

MICROSCOPIC

HISTOLOGIC TYPE

Hepatocellular carcinoma

HISTOLOGIC GRADE

Nuclear grade 2 of 3 (Lauwers grade)

MARGINS

Uninvolved by tumor

Distance to nearest margin is 0.4 cm

LIVER CAPSULE

No tumor present

LYMPHATIC/VASCULAR INVASION

Absent: Lymph-vascular invasion not present/Not identified

TUMOR EXTENSION

Tumor confined to liver

MITOTIC ACTIVITY

3/10 HPF

HEPATOCELLULAR PROGNOSTIC INDEX

Fair prognosis - Grade 2 without vascular invasion

hw
11/4/12

PATHOLOGIC STAGING

EXTENT OF INVASION

[page 2 of 3]
[REDACTED]

pT1. (Solitary tumor without vascular invasion)
REGIONAL LYMPH NODES
pNX. (Cannot be assessed)
DISTANT METASTASIS
pM0. (No distant metastasis)
PATHOLOGIC STAGE Summary
Final TNM: pT1NXM0
2010 stage: I
** The pathologic stage presumes no distant metastasis.

PROGNOSTIC FACTORS (SITE SPECIFIC FACTORS)

CIRRHOSIS
Present
SMALL CELL DYSPLASIA
Absent

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

The patient has a solitary liver mass. Per the Record, has a past medical history that includes hepatitis C (no specific hepatitis C studies are present within

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Right partial hepatectomy, section 7
Labeled "right partial hepatectomy, section 7" is a 402 gm, 10 x 9.8 x 7.7 cm partial liver resection. The margin is inked black. The cut surfaces disclose a 9.5 x 8 x 7.5 cm solid circumscribed tumor mass with variegated and lobulated yellow-tan, hemorrhagic surfaces, extending to 0.4 cm from the black-inked surgical resection margin.

INTRAOPERATIVE PATHOLOGY CONSULTATION: "Margin negative by approximately 4 mm (0.4 cm)" is rendered by [REDACTED]

The uninvolved adjacent portions of liver parenchyma disclose irregular nodularity, appear fibrotic and red-tan, without additional discretely separate nodules.

Photographs of the specimen are taken. Tissue is banked for additional possible ancillary studies. Representative sections are submitted in seven cassettes as follows:

- 1-3. Tumor mass and margin (inked black)
4. Tumor, central portion
5. Tumor with pale tan fleshy component
- 6,7. Uninvolved liver with nodular cut surfaces

This case is accessioned in

Gross dictation by: [REDACTED]

MICROSCOPIC

The hepatocellular carcinoma is overall moderate to poorly differentiated (grade 3 of 4) and shows a Lauwers nuclear grade 2 of 3. There are large areas of clear cell hepatocellular carcinoma as well as a focus of chondroid metaplasia. The background liver shows bridging fibrosis with well-formed micronodules. There is minimal interface hepatitis. There is no evidence of steatohepatitis.

[page 3 of 3]
[REDACTED]

Dictation by:

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL
Information

ab and Collection

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL
Report

Order Result History

Lab Status

Order Complete [3]

Result Information

Result Date and Time

Status

Final result

Provider Status
Ordered

Lab Information

Lab

Order Details

Parent Order ID

Child Order ID

Entry Date

Specimen Information

Specimen Source

Collection Date

Collection Time

Audit Trail

Action

User

Date/Time

Order Printed

Order Printed

MyChart Status:

This result is currently not released to

Order

GROSS AND MICROSCOPIC SURGICAL PANEL

Order Information Date

Ordering User

Department

Reviewed Initials		

11/4/12

Source: NCI Genomic Data Commons file 84f8932e-73d7-4c6d-8075-02c7b59882fc (TCGA-FV-A4ZQ.C0B03F38-09C0-4B87-94BC-E2E8D9F7F922.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).